Somatic mutation profile of tumor specimen MP2PRT-PAREKT-TMP1-A (aliquot MP2PRT-PAREKT-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAREKT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,360 days).
Specimen MP2PRT-PAREKT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 263e74e1-32e7-4551-9e4a-1e22a721f501.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAREKT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAREKT-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c19a767e-f26a-46da-a8e3-2b55643466a3

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Silent 3, Missense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.5408G>A p.R1803H | Missense Mutation (SNP) | VAF 163/394 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs750373293; called by muse, mutect2, varscan2
- RBM3 | c.205G>A p.G69R | Missense Mutation (SNP) | VAF 153/692 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs781917689; called by muse, mutect2, varscan2
- IGHV4-61 | c.355_356insTCGTTAGGTCGAGAG | In Frame Ins (INS) | VAF 26/239 reads (11%) | called by pindel, varscan2*
- ADGRB1 | c.3579C>T p.D1193= | Silent (SNP) | VAF 118/448 reads (26%) | catalogued as rs577752659; called by muse, varscan2
- TGFBR1 | c.855T>C p.H285= | Silent (SNP) | VAF 144/447 reads (32%) | catalogued as COSV100895408; called by muse, mutect2, varscan2
- ZNF615 | c.582A>G p.Q194= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
